Somatic mutation profile of tumor specimen 0DEA0S from CCDI case PBBPHZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (433 days).
Specimen 0DEA0S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf26d3fb-47db-4e2c-afce-42c347ffc7ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEA0O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4007367-5f1c-408e-97d2-dae8d824e321

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP45 | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 73/900 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs142022446; called by muse, mutect2
- MAGEB6B | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 66/664 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2
- DNAH2 | c.1904+385G>A | Intron (SNP) | VAF 7/12 reads (58%) | catalogued as rs998723356; called by muse, varscan2
